Gene-level copy-number profile of tumor specimen ALCH-AE2G-TTP1-A from ALCHEMIST case ALCH-AE2G, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 47.3 years (17,292 days).
Specimen ALCH-AE2G-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ab4c9650-50b3-48dc-b9a6-03ef04449d96.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE2G-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/f38cceaa-1c90-4d1c-be7a-332f639bf8b4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 76; copy number 2: 58,300; copy number 3: 1; copy number 4: 2; copy number 5: 1; copy number 6: 1; copy number 7: 1; copy number 9: 5; copy number 13: 1; copy number 20: 1; copy number 22: 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,613,758–1,615,795, 1 gene (within-gene range 0–2): AL691432.2.
- chr1:27,525,805–27,604,431, 2 genes: BX293535.1, AHDC1.
- chr11:59,531,754–59,532,695, 1 gene: OR4D7P.
- chr16:29,380,242–29,404,029, 2 genes: AC025279.3, NPIPB11.
- chr19:38,388,421–38,409,088, 2 genes (within-gene range 0–2): SPRED3, FAM98C.
- chr19:58,034,025–58,054,631, 3 genes (within-gene range 0–2): ZSCAN1, LETM1P2, HNRNPDLP4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,598,012–1,600,135, 1 gene, copy number 22: FNDC10.
- chr1:32,402,109–32,403,115, 1 gene, copy number 6: GAPDHP20.
- chr5:181,291,673–181,342,213, 5 genes, copy number 9: AC008443.5, RNU6-705P, AC138035.1, AC138035.3, AC138035.2.
- chr9:127,731,524–127,735,313, 1 gene, copy number 13 (within-gene range 2–13): TOR2A.
- chr16:4,257,186–4,273,075, 1 gene, copy number 5: TFAP4.
- chr16:90,039,761–90,047,773, 1 gene, copy number 20 (within-gene range 2–20): URAHP.
- chr22:20,299,760–20,313,216, 1 gene, copy number 7: AC007663.1.

Autosomal genes at a single copy (total copy number 1): 76. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
